Surgical pathology report (de-identified scan), TCGA case TCGA-MH-A857, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site BLN - Baylor, specimen TCGA-MH-A857-01A (Primary Tumor).

[page 1 of 3]
----- SURGICAL PATHOLOGY -----

MEDICAL RECORD

SURGICAL PATHOLOGY

PATHOLOGY REPORT

Laboratory:

Accession No.

Submitted by:

Date obtained:

Specimen (Received

A.BASE OF LEFT RENAL TUMOR F.S.

B.LEFT RENAL PERITUMOR FAT

C.LEFT RENAL TUMOR

*ICD-O-3
Carcinoma, papillary renal cell 8260/3
Site @ Kidney NOS C64.9
JW 11/29/13*

BRIEF CLINICAL HISTORY:

PREOPERATIVE DIAGNOSIS:

left renal mass

OPERATIVE FINDINGS:

POSTOPERATIVE DIAGNOSIS:

left renal mass

Surgeon/physician:

PATHOLOGY REPORT

Laboratory:

Accession No.

GROSS DESCRIPTION:

A. The specimen is received fresh for intraoperative consultation and consists of a 1.2 x 0.4 x 0.3 cm tan-yellow irregular tissue fragment that is submitted in toto for frozen and permanent section in cassette FSA.

FROZEN SECTION DIAGNOSIS:

FSA. Base of left renal tumor, biopsy:
- NO TUMOR SEEN

B. The specimen consists of a 173 gm, 11.2 x 6.5 x 3.2 cm tan-yellow aggregate of fatty soft tissue partially surfaced by a tan-pink smooth glistening peritoneal surface. No discrete lesions are identified. Sectioning reveals a tan-yellow unremarkable fatty cut surface. Representative sections are submitted in cassettes B1-B6.

C. The specimen consists of a 54.7 gm, 5.5 x 5.2 x 3.8 cm partial nephrectomy specimen partially surfaced by a tan-brown scabrous renal resection margin. The capsular margin is partially surfaced by tan yellow lobulated fat. The renal resection margin is inked blue and the capsular margin is inked black.

[page 2 of 3]
The specimen is serially sectioned to reveal a 4.6 x 3.8 x 3.2 cm tan-yellow to brown to red variegated poorly demarcated mass that grossly extends less than 1 mm from the renal resection margin and 0.4 cm from the overlying Gerota's fascia/capsular margin. There is a minimal amount of uninvolved renal parenchyma at the renal resection margin.

Representative sections of the majority of the mass, to include the capsular and renal resection margins, are submitted sequentially in cassettes C1-C17. (Please note that a representative portion is taken for

MICROSCOPIC EXAM

DIAGNOSIS:

- A. Base of left renal tumor, excision:
- NO TUMOR IDENTIFIED
- B. Left renal peritumor fat, excision:
- FIBROADIPOSE TISSUE, NO TUMOR IDENTIFIED
- C. Left renal tumor, partial nephrectomy:
- PAPILLARY RENAL CELL CARCINOMA
- CHROMOPHOBE RENAL CELL CARCINOMA
- (SEE SYNOPTIC REPORT)

SYNOPTIC REPORT:

PROCEDURE: Partial nephrectomy

SPECIMEN LATERALITY: Left

TUMOR SIZE:

Greatest dimension:

1.8 cm (chromophobe renal cell carcinoma)

1.6 cm (papillary renal cell carcinoma)

TUMOR FOCALITY: Multifocal

MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney

HISTOLOGIC TYPE: Papillary renal cell carcinoma
Chromophobe renal cell carcinoma

SARCOMATOID FEATURES: Not identified

TUMOR NECROSIS: Present

HISTOLOGIC GRADE:

G2 (papillary renal cell Carcinoma)

Not applicable (chromophobe renal cell carcinoma)

MICROSCOPIC TUMOR EXTENSION: Tumor limited to kidney

MARGINS: Margins uninvolved by invasive carcinoma
(Closest margin: Papillary renal cell carcinoma
1 mm from capsular margin;

[page 3 of 3]
Chromophobe renal cell carcinoma 1 mm from renal
parenchymal margin)

LYMPH-VASCULAR INVASION: Not identified

PATHOLOGIC STAGING:

Chromophobe renal cell carcinoma: pT1,pNX,pMX

Papillary renal cell carcinoma: pT1,pNX,pMX

COMMENT: By immunohistochemistry the chromophobe RCC is positive for CK7, and negative for CD15, vimentin and 504s. The papillary RCC is positive for 504s.

concur with the diagnosis. Physician was notified at the time of frozen section and via on

Immunohistochemistry Disclaimer: "This test was developed and its performance characteristics determined by the at the

It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This Laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing."

JPAA Discrepancy		✓

Source: NCI Genomic Data Commons file b8603bff-a399-4b51-8719-4c2ddab8bc2c (TCGA-MH-A857.465C49A8-2050-434A-AC95-9144E46972DB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).